Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-7064, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-7064-01A (Primary Tumor).

[page 1 of 6]
Patient Name	MRN	Visit Number

Event Date and Time	Procedure Ordered	Status	Ordered By	Specimen #
	Surgical Pathology Report	complete		
Collection Date				
Accession Date				
Result Date				
Copath#				

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Nck: Left neck level I
2. Nck: Left neck level II
3. Nck: Left neck level III
4. Nck: Left neck level IV
5. Muscle: pterygoid muscle
6. Oral Cavity: left buccal tumor (suture anterior resection margin)
7. Soft Tissue: intertemporal fossa fat
8. Oral Cavity: interior maxillary margin
9. Oral Cavity: anterior buccal margin
10. Soft Tissue: posterior inferior mucosal margin
11. Oral Cavity: inferior anterior mucosal margin
12. Oral Cavity: inferior alveolar margin
13. Oral Cavity: posterior mucosal margin

DIAGNOSIS

1. Left neck level I.

Metastatic squamous cell carcinoma involving one of four lymph nodes (1/4).

- a. The lymph node involved measures 1.6 cm.
- b. Extranodal invasion is present.

Submandibular gland with no pathologic changes.

2. Left neck level II.

Eleven lymph nodes negative for tumor (0/11).

3. Left neck level III.

Three lymph nodes negative for tumor (0/3).

4. Left neck level IV.

Twelve lymph nodes negative for tumor (0/12).

5. Pterygoid muscle.

Negative for tumor.

5. Oral cavity; left buccal tumor; resection.

[page 2 of 6]
Squamous cell carcinoma, moderately differentiated.

- a. Maximum tumor diameter 4.4 cm.
- b. Tumor thickness 2.6 cm.
- c. No lymphovascular invasion.
- d. No perineural invasion.
- e. Tumor present at the deep margin of the specimen. The remaining margins are negative for tumor.

7. Intertemporal fossa fat.

Negative for tumor.

8. Interior maxillary margin.

Negative for tumor.

9. Anterior buccal margin.

Negative for tumor.

10. Posterior inferior mucosal margin.

Negative for tumor.

11. Inferior anterior mucosal margin.

Negative for tumor.

12. Inferior alveolar margin.

Negative for tumor.

13. Posterior mucosal margin.

Negative for tumor.

SYNOPTIC DATA

Specimen Type: Resection:left buccal tumor; resection

Tumor Site: Oral Cavity

Histologic Type: Squamous cell carcinoma, conventional

Tumor Size: Greatest dimension: 4.4 cm

Tumor thickness: 2.6 cm

Histologic Grade: G2: Moderately differentiated

Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Absent

Perineural Invasion: Present

Additional Pathologic Findings: None identified

Margins: Margins uninvolved by tumor

Pathologic Staging (pTNM): pT3: Tumor or lip or oral cavity more than 4 cm in greatest dimension

pN1: Metastasis in a single ipsilateral

lymph node, 3 cm or less in greatest dimension for all aerodigestive sites except nasopharynx

Number of regional lymph nodes

examined: 30

[page 3 of 6]
Number of regional lymph nodes

involved: 1

Extra-capsular extension of nodal tumor:

Present

pMX: Distant metastasis cannot be assessed

ELECTRONICALLY VERIFIED BY:

GROSS DESCRIPTION

1. The specimen is labeled with the patient's name and "left neck level I". It consists of portion of fibroadipose tissue measuring 4.8 x 5.3 x 1.7 cm. A grossly unremarkable submandibular gland is identified measuring 4.2 x 2.5 x 1.7 cm. Multiple lymph nodes ranging from 0.3 x 0.3 x 0.4 to 1.6 x 1.4 x 1.3 cm are identified. Representative sections are submitted.

1A submandibular gland

1B-1C one lymph node serially sectioned

1D one lymph node

1E multiple lymph nodes

1F one lymph node

2. The specimen is labeled with the patient's name and "left neck level II".

It consists of portion of fibroadipose tissue measuring 3.9 x 2.8 x 1.4 cm.

Multiple lymph nodes ranging from 0.6 x 0.4 x 0.4 to 1.6 x 1.4 x 1.0 cm are identified. Representative sections are submitted.

2A multiple lymph nodes

2B one lymph node

2C multiple lymph nodes

2D one lymph node

2E one lymph node

3. The specimen is labeled with the patient's name and as "left neck level III". It consists of a piece of fibroadipose tissue measuring 3.8 x 1.9 x 3.5 cm. Three lymph nodes ranging from 0.4 x 0.4 x 0.3 to 2.2 x 0.6 x 0.5 are identified. The lymph nodes are submitted in toto.

3A two lymph nodes

3B one lymph node

4. The specimen is labeled with the patient's name and "left neck level IV".

It consists of portion of fibroadipose tissue measuring 2.8 x 1.6 x 1.5 cm.

Multiple lymph nodes ranging from 0.3 x 0.2 x 0.2 to 1.3 x 0.6 x 0.7 cm are identified. Representative sections are submitted.

4A multiple lymph nodes

4B one lymph node

[page 4 of 6]
4C one lymph node

4D multiple lymph nodes

5. The specimen is labeled with the patient's name and as "muscle pterygoid". It consists of a fragment of tissue measuring 0.5 x 0.3 x 0.3 cm. The specimen is submitted in toto for frozen section.

5A frozen section control

6. The specimen is labeled with the patient's name and as "left buccal tumor suture anterior resection margin". It consists of an oriented portion of mucosa measuring 5.0 SI x 3.0 ML x 7.0 cm AP. A centrally ulcerated tumor is identified. The tumor extends to the deep soft tissue and measures 3.3 SI x 2.6 ML x 4.4 AP. The tumor is tan, solid and firm. The tumor is at 1.2 cm from the anterior margin, 1.0 cm from the inferior margin, and 0.6 cm from the posterior margin, 0.7 cm from the superior margin and very close to the deep soft tissue margin. Two representative sections representative sections of the tumor including the deep margin are submitted for frozen section.

Representative sections are submitted.

6A-6B frozen section resubmitted

6C anterior margin

6D tumor with superior margin

6E tumor with posterior margin

6F tumor with inferior margin

6G-6J tumor with deep soft tissue margin

7. The specimen is labeled with the patient's name and as "inferior temporal fossa fat". It consists of two fragments of tissue measuring 0.1 x 0.4 x 0.2 and 0.6 x 0.3 x 0.3 cm. The specimen is submitted in toto for frozen section.

7A frozen section control

8. The specimen is labeled with the patient's name and as "inferior maxillary margin". It consists of a fragment of tissue measuring 1.1 x 0.2 x 0.1 cm.

The specimen is submitted in toto for frozen section.

8A frozen section control

9. The specimen is labeled with the patient's name and as "anterior buccal margin". It consists of a fragment of tissue measuring 1.2 x 0.2 x 0.2 cm.

The specimen is submitted in toto for frozen section.

9A frozen section control

10. The specimen is labeled with the patient's name and as "posterior inferior mucosal margin". It consists of a fragment of tissue measuring 1.0 x 0.2 x 0.2 cm. The specimen is submitted in toto for frozen section.

10A frozen section control

11. The specimen is labeled with the patient's name and as "inferior anterior

[page 5 of 6]
mucosal margin". It consists of a fragment of tissue measuring 0.9 x 0.2 x 0.2 cm. The specimen is submitted in toto for frozen section.

11A frozen section control

12. The specimen is labeled with the patient's name and as "inferior alveolar margin". It consists of a fragment of tissue measuring 1.0 x 0.2 x 0.1 cm.

The specimen is submitted in toto for frozen section.

12A frozen section control

13. The specimen is labeled with the patient's name and as "posterior mucosal margin". It consists of a fragment of tissue measuring 0.2 x 0.2 x 0.2 cm.

The specimen is submitted in toto for frozen section.

13A frozen section control

QUICK SECTION

5. Pterygoid muscle: QS5A Negative for malignancy.

6. Left buccal tumor, suture anterior resection margin: QS6A, 6B Tumor within microscopic distance (<1mm), but not seen at inked surface.

7. Intertemporal fossa fat: QS7A Negative for malignancy.

8. Interior maxillary margin: QS8A Negative for malignancy.

9. Anterior buccal margin: QS9A Negative for malignancy.

10. Posterior-inferior mucosal margin: QS10A Negative for malignancy.

11. Inferior-anterior mucosal margin: QS11A Negative for malignancy.

12. Inferior alveolar margin: QS12A Negative for malignancy.

13. Posterior mucosal margin: QS13A Negative for malignancy.

Reported in person to clinical fellow

Source: NCI Genomic Data Commons file 9bff23f3-5c18-4155-9ea1-b9380aa8ff0c (TCGA-CQ-7064.7A1C1058-547F-463F-AD3E-371E6C5F9EEA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).